Gene-level copy-number profile of tumor specimen C3N-00177-02 from CPTAC case C3N-00177, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 52.5 years (19,161 days).
Specimen C3N-00177-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d266d297-fecf-4f8a-b5fd-03d2c9c4e282.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00177-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/3ee7d453-4c29-4b78-86a9-286c98582eac

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,961; copy number 2: 54,765; copy number 3: 1,189; copy number 5: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:74,773,962–74,789,376, 1 gene, copy number 5: NCF1.

Autosomal genes at a single copy (total copy number 1): 105. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
